Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8105, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8105-01A (Primary Tumor).

Microscopic

Permanent section of the frozen section ;specimen demonstrates a mildly to moderately hypercellular glial neoplasm that diffusely infiltrates the parenchyma. A large area of biopsy demonstrates extensive dystrophic calcification with adjacent and intermingled tumor cells. The tumor cells have round to oval nuclei and few apparent processes. Atypia is mild to moderate. No mitotic figures are seen.

Addendum

Sections demonstrate a markedly hypercellular diffusely infiltrative glioma essentially as previously described. Again, the tumor cells quite consistently have perinuclear halos. Nuclei tend to be round, although some oblong nuclei are seen. Atypia is generally moderate. Although proliferative activity is variable, up to 17 mitoses are seen in 10 high power fields. Microvascular proliferation is present and there is a single focus of non pseudopalisading necrosis. Numerous MIB-1 reactive cells are present throughout the tumor. A labeling index of 39.8% is calculated.

Diagnosis

Anaplastic oligodendroglioma,, Grade III

Source: NCI Genomic Data Commons file a544cddf-ee04-4c54-a898-f5cad5c6264c (TCGA-HT-8105.D7C51467-5BAA-4858-86BD-CFB6D9344A05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).